Surgical pathology report (de-identified scan), TCGA case TCGA-61-1913, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1913-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY -

- A. POORLY DIFFERENTIATED SEROUS CARCINOMA OF RIGHT OVARY.
- B. CHRONIC SALPINGITIS, RIGHT.

PART 2: UTERUS WITH LEFT ADNEXA (188 GRAMS), TOTAL ABDOMINAL HYSTERECTOMY AND LEFT SALPINGO-OOPHORECTOMY -

- A. CHRONIC CERVICITIS, SQUAMOUS METAPLASIA AND MICROGLANDULAR HYPERPLASIA.
- B. PROLIFERATIVE ENDOMETRIUM.
- C. LEIOMYOMAS, UP TO 0.7 CM.
- D. LEFT OVARY WITH HEMORRHAGIC CORPUS LUTEUM.
- E. CHRONIC SALPINGITIS, LEFT.

PART 3: MULTIPLE PELVIC NODULES, EXCISION - METASTATIC SEROUS CARCINOMA.

PART 4: RIGHT PELVIC LYMPH NODES, DISSECTION - FIBROADIPOSE TISSUE. NO LYMPH NODES IDENTIFIED.

PART 5: LEFT PELVIC LYMPH NODES, DISSECTION -

- A. TWO LYMPH NODES NEGATIVE FOR TUMOR (0/2).
- B. SEPARATE NODULE CONTAINING METASTATIC CARCINOMA SURROUNDED BY THE REACTIVE FIBROUS TISSUE (SEE COMMENT).

PART 6: RIGHT PERIAORTIC LYMPH NODES, DISSECTION - THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 7: OMENTUM, OMENTECTOMY - FOCAL MICROSCOPIC METASTATIC CARCINOMA.

PART 8: DIAPHRAGM, BIOPSY - NEGATIVE FOR TUMOR.

PART 9: APPENDIX, APPENDECTOMY - UNREMARKABLE VERMIFORM APPENDIX.

PART 10: LEFT PERIAORTIC LYMPH NODES, DISSECTION - TWO (2) LYMPHNODES, NEGATIVE FOR TUMOR (0/2).

PART 11: LEFT PERICOLIC GUTTER, BIOPSY - NEGATIVE FOR TUMOR.

PART 12: RIGHT PERICOLIC GUTTER, BIOPSY - NEGATIVE FOR TUMOR.

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Right
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 14 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Omentum
SURFACE IMPLANT SIZE:	< 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	No
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 7
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Left: 0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pM0
FIGO STAGE:	IIIB

Source: NCI Genomic Data Commons file de2caca7-f1ec-4a55-95c9-1a09a0ee0afb (TCGA-61-1913.B789EE6D-D1E2-4836-8BDC-3C59B0729EE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).